Surgical pathology report (de-identified scan), TCGA case TCGA-14-1453, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1453-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

Document Type: AP Report
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info: [REDACTED] - [REDACTED]

TCGA-14-1453

* Final Report *

AP REPORT

Patient: [REDACTED] Accession Number: [REDACTED]
Patient Number: [REDACTED] Date Collected: [REDACTED]
Financial Number: [REDACTED] Date Received: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT PARIETAL, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME.
- SEE COMMENT.
2. BRAIN, LEFT PARIETAL, EXCISION:
- GLIOBLASTOMA MULTIFORME.
- SEE COMMENT.

COMMENT:

This glioblastoma is highly cellular and anaplastic with focal giant cell pattern. Necrosis, microvascular proliferation and mitotic activity are all identified.

SPECIMEN:

1. Left parietal brain lesion.
2. Left parietal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 3
(Continued)

[page 2 of 2]
AP Report

* Final Report *

Brain tumor.

GROSS DESCRIPTION:

Two specimens are received, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation, labeled "left parietal brain lesion" and consists of tan tissue, measuring 1.3 x 0.7 x 0.5 cm. A representative section is submitted for frozen tissue diagnosis, and the contents of the cryoblock are submitted in cassette "1A." The remainder of the specimen is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "left parietal brain lesion" and consists of one piece of brain tissue measuring 2.9 x 2.5 x 1.0 cm. A hemorrhagic mass measuring 2.5 x 1.3 x 1.0 cm is present within the specimen. Representative sections are submitted in cassettes "2A" and "2B."

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT PARIETAL BRAIN LESION (FROZEN SECTION): GLIOBLASTOMA.

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 3
(Continued)

Source: NCI Genomic Data Commons file e1ab6def-8388-4d86-8089-4366e55f60bc (TCGA-14-1453.2652E3CF-CCBC-4433-A46E-400AFEFA925D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).